Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4977, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4977-01A (Primary Tumor).

[page 1 of 2]
Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

with left upper pole renal mass.

TCGA - BP - 4977

Specimens Submitted:

- 1: KIDNEY, LEFT UPPER POLE, PARTIAL NEPHRECTOMY
- 2: "DEEP MARGIN COLLECTING SYSTEM ON SINUS FAT," BIOPSY

DIAGNOSIS:

1. KIDNEY, LEFT UPPER POLE, PARTIAL NEPHRECTOMY

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade III/IV

Tumor Size:

Greatest diameter is 4.5 cm.

Local Invasion (for renal cortical types):

Not Identified

Renal Vein Invasion:

Not present for evaluation.

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Multiple papillary adenomas are present.

Adrenal Gland:

Not Identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

2. "DEEP MARGIN COLLECTING SYSTEM ON SINUS FAT," BIOPSY

- Benign urothelial mucosa with chronic inflammation.
- Benign renal parenchyma.

[page 2 of 2]
Note:

has reviewed select slides in Part 1 of this case and concurs with the diagnoses.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Gross Description:

1.) The specimen is received fresh and is labeled "Left upper pole partial nephrectomy peritumoral fat". It consists of a 11.5 x 7.2 x 5.6 cm wedge shaped portion of kidney with overlying perinephric fat. The kidney measures 6.5 x 5.5 x 4.6 cm. There is a suture marking the deep margin. The margin is inked black and the specimen is serially sectioned to reveal a well-circumscribed yellow tumor with areas of hemorrhage and focal areas of cystification, measuring 4.5 cm in greatest dimension. The tumor is confined by the renal capsule. The clearance from the resection margin is 0.2 cm. The remainder of the specimen consists of renal parenchyma with a white well defined 0.4 cm subcapsular lesion, located 0.9 cm away from the main tumor. Representatively submitted. Portions of the tumor are submitted for TPS.

Summary of sections:

T - tumor

M - margin

RS - representative sections

2.) The specimen is received in formalin, labeled "deep margin collecting system on sinus fat", and consists of one irregularly shaped fragment of white-tan soft tissue with attached yellow lobulated adipose tissue, measuring 1.7 x 1.2 x 0.2 cm. Entirely submitted.

Summary of sections:

U -- undesignated

Summary of Sections:

Part 1: KIDNEY, LEFT UPPER POLE, PARTIAL NEPHRECTOMY

Block	Sect. Site	PCs
1	m	1
1	rs	1
4	t	4

Part 2: "DEEP MARGIN COLLECTING SYSTEM ON SINUS FAT," BIOPSY

Block	Sect. Site	PCs
1	u	1

Source: NCI Genomic Data Commons file 0284657b-545e-41e6-931d-fec0263260a4 (TCGA-BP-4977.34A3C089-4E82-48A9-9641-74927A3CCCB4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).